Gene-level copy-number profile of tumor specimen TCGA-T2-A6WZ-01A from TCGA case TCGA-T2-A6WZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G2; Age at diagnosis: 53.1 years (19,397 days).
Specimen TCGA-T2-A6WZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3873a52f-6e4e-4544-810d-d4a164a70d51.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-T2-A6WZ-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c6bf126-b7da-478a-80c3-910ef5e76b2a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 1,681; copy number 2: 26,840; copy number 3: 13,991; copy number 4: 8,636; copy number 5: 6,838; copy number 6: 1,117; copy number 7: 545; copy number 8: 95; copy number 10: 14; copy number 11: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-T2-A6WZ-01A-21D-A34I-01): tumor purity 0.49, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,643,706–85,276,632, 12 genes (within-gene range 0–2): SSX2IP, AC104169.1, LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10.
- chr3:9,292,588–9,398,579, 4 genes (within-gene range 0–2): AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3.
- chr5:59,039,761–59,314,800, 2 genes: AC092343.1, AC008833.1.
- chr5:119,268,692–119,399,688, 2 genes (within-gene range 0–2): TNFAIP8, RN7SL174P.
- chr9:9,090,898–9,442,380, 2 genes: RPS26P3, RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,591 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–9,129,102, 311 genes, copy number 5–6 (broad region; genes not listed).
- chr1:9,151,668–9,151,777, 1 gene, copy number 5: MIR34A.
- chr2:97,050,729–131,047,263, 632 genes, copy number 6 (broad region; genes not listed).
- chr3:93,843,764–133,397,775, 673 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:133,661,998–143,848,485, 178 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:143,620,528–174,378,005, 439 genes, copy number 5 (broad region; genes not listed).
- chr3:175,609,479–198,222,513, 491 genes, copy number 5 (broad region; genes not listed).
- chr4:46,390,255–46,993,581, 5 genes, copy number 7 (within-gene range 2–7): AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4.
- chr5:58,198–32,110,932, 478 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr5:32,124,716–45,895,970, 228 genes, copy number 5 (broad region; genes not listed).
- chr6:53,929,982–55,579,197, 19 genes, copy number 5–11 (within-gene range 2–11): MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1.
- chr7:4,130,181–33,109,404, 500 genes, copy number 5 (broad region; genes not listed).
- chr7:33,128,988–33,277,091, 3 genes, copy number 5: AC074338.1, RNA5SP229, AC007312.1.
- chr7:52,165,235–62,275,678, 176 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–120,056,201, 1,078 genes, copy number 5 (broad region; genes not listed).
- chr8:120,380,761–145,066,685, 455 genes, copy number 5–7 (broad region; genes not listed).
- chr9:558,826–558,930, 1 gene, copy number 6: RNU6-1327P.
- chr9:85,159,682–138,203,325, 1,172 genes, copy number 5 (broad region; genes not listed).
- chr10:4,201,141–34,815,325, 519 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:34,663,859–38,783,108, 87 genes, copy number 5 (broad region; genes not listed).
- chr10:43,728,217–45,176,925, 38 genes, copy number 6 (within-gene range 2–6): SPRING1P1, UQCRHP3, ELOCP30, LINC02658, LINC00840, HNRNPA3P1, LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, AL137026.3, CXCL12, RPL9P21, AL356157.2, AL356157.3, AL356157.1, TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7, RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1.
- chr10:45,615,500–47,002,488, 44 genes, copy number 5: ZFAND4, AGAP10P, FAM21FP, AL645998.1, WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R, GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, FAM245B, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P, FRMPD2B, PTPN20.
- chr11:58,203,202–59,208,588, 44 genes, copy number 6 (within-gene range 4–6): OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4, GLYATL1B, FAM111B, FAM111A-DT, AP001258.1, FAM111A, DTX4.
- chr12:57,693,955–58,395,138, 32 genes, copy number 6: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr16:58,733,910–59,199,395, 1 gene, copy number 5 (within-gene range 4–5): AC106793.1.
- chr16:58,825,891–63,618,046, 34 genes, copy number 5: RPL12P36, AC092378.1, Metazoa_SRP, RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3.
- chr17:6,749,685–9,576,591, 168 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:47,390–5,385,330, 113 genes, copy number 5–8 (broad region; genes not listed).
- chr18:5,721,812–5,989,369, 4 genes, copy number 8 (within-gene range 2–8): MIR3976HG, MIR3976, TMEM200C, AP001021.1.
- chr18:5,956,101–5,960,785, 1 gene, copy number 8: AP001021.2.
- chr18:6,454,962–6,642,478, 7 genes, copy number 8: RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1.
- chr19:27,638,483–29,617,237, 47 genes, copy number 6–7: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4.
- chr20:87,250–21,755,350, 421 genes, copy number 5–8 (broad region; genes not listed).
- chr20:25,669,857–34,834,462, 191 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,361. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
